TCGA case TCGA-BC-A10U — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/23103931-cc29-4f89-ae9c-79d53401ecea

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Dead; Days to death: 837 days (2.3 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 69.3 years (25,305 days); Year of diagnosis: 2000; AJCC staging edition: 5th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Ablation, Radiofrequency; Days to treatment start: 614 days (1.7 years); Number of cycles: 1; Lesions treated number: 2.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS). Age at diagnosis: 70.9 years (25,891 days); Days to diagnosis: 586 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 586 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to recurrence: 586 days (1.6 years).
- Days to follow up: 837 days (2.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1.
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.4].
- Platelets 204000 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 440].
- Total Bilirubin 0.4 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].
- Alpha Fetoprotein 38 ng/mL.
- Albumin 4.3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption.

Family history
- Relatives with cancer history count: 4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BC-A10U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 510 mg.
  Slide TCGA-BC-A10U-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BC-A10U-01A-01-BSA: Section location: Bottom; Percent tumor cells: 96; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BC-A10U-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BC-A10U-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 1,130 mg.
  Slide TCGA-BC-A10U-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: Yes.
- Ablations, Ablation, Ablation treatments, Ablation treatment: Ablation type: Radiofrequency Ablation; Treatment cycles count: 1; Lesions count: 2.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 837 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 837 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 586 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BC-A10U-01A-11D-A12Y-01): tumor purity 0.86, ploidy 2.07, whole-genome doublings 0.
